Surgical pathology report (de-identified scan), TCGA case TCGA-4K-AA1G, project TCGA-TGCT (Testicular Germ Cell Tumors), tissue source site Proteogenex, Inc., specimen TCGA-4K-AA1G-01A (Primary Tumor).

Age/Sex: years / M

Date:

Procedure: Left orchiectomy

Preoperative diagnosis: TUMOR OF THE LEFT TESTIS

Postoperative diagnosis: SEE MICROSCOPIC DIAGNOSIS BELOW

Specimen(s): 1. LEFT TESTIS

Diagnosis:

1. LEFT TESTIS:

- Seminoma
- Tumor invades the tunica albuginea and the epididymis
- Vascular invasion is present
- Resection margin and scrotum are free of tumor

Gross description:

1. LEFT TESTIS:

Received fresh, is a left testis 14.0 x 10.0 x 8.0 cm in dimensions with a portion of the spermatic cord 5.0 cm in length and a part of the scrotum 7.0 x 5.0 x 1.5 cm in dimensions, en bloc. The testis is fully replaced by the lobulated whitish-gray tumor 13.0 x 8.0 x 8.0 cm in dimensions.

ICD.O-3

Seminoma NOS 9061/3
Site: ⊙ Testis NOS C62.9
4/11/27/14

Source: NCI Genomic Data Commons file 8f73d903-9ff2-4758-a0ed-33275740a71d (TCGA-4K-AA1G.BBBC802D-5C22-4DCA-9B9F-00DDDC7D8373.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).